Gene-level copy-number profile of tumor specimen TCGA-DB-5277-01A from TCGA case TCGA-DB-5277, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 34.8 years (12,725 days).
Specimen TCGA-DB-5277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.0f07c9ff-3ad3-4ec0-873b-a2ba0a35e196.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DB-5277-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6054917f-fa65-43b3-bc08-6ceb7e604fa7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 2,257; copy number 2: 15,992; copy number 3: 12,327; copy number 4: 23,048; copy number 5: 1,911; copy number 6: 1,743; copy number 7: 1,145; copy number 8: 940; copy number 9: 185; copy number 11: 213.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DB-5277-01A-01D-1466-01): tumor purity 0.9, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,840,512, 45 genes (within-gene range 0–2): FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1, AC018685.2, AC018685.3, AC011995.2, AC018685.1.
- chr9:22,203,990–22,455,740, 2 genes (within-gene range 0–2): AL157937.1, DMRTA1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 398 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:119,730,774–132,111,159, 185 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr10:4,384,246–4,515,244, 5 genes, copy number 9: LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P.
- chr10:7,295,106–18,940,953, 178 genes, copy number 9 (broad region; genes not listed).
- chr10:19,051,455–19,291,480, 2 genes, copy number 9: UBE2V2P1, AL590378.1.
- chr19:17,511,636–18,151,692, 28 genes, copy number 11 (within-gene range 6–11): PGLS, AC010618.2, NIBAN3, COLGALT1, AC010618.1, UNC13A, AC008761.2, AC008761.3, MAP1S, AC008761.1, FCHO1, B3GNT3, INSL3, JAK3, RPL18A, SNORA68, AC005796.1, SLC5A5, CCDC124, KCNN1, RNA5SP468, ARRDC2, AC020904.3, AC020904.2, AC020904.1, RPS18P13, IL12RB1, MAST3.

Autosomal genes at a single copy (total copy number 1): 1,035. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
